Somatic mutation profile of tumor specimen TCGA-GN-A267-06A (aliquot TCGA-GN-A267-06A-21D-A196-08) from TCGA case TCGA-GN-A267, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 42.5 years (15,521 days).
Specimen TCGA-GN-A267-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1b18f14-9490-4db8-a446-32e13b838015.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A267-10A (Blood Derived Normal), aliquot TCGA-GN-A267-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24587f91-94a3-403b-a650-b9ef5d9f11b3

The open-access MAF lists 521 somatic variants for this specimen: 336 protein-altering or splice-affecting, 171 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 296, Silent 171, Nonsense Mutation 21, Intron 9, Splice Region 6, In Frame Del 4, Splice Site 4, Frame Shift Del 4, RNA 2, 5'UTR 2, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL4 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as rs746887961, COSV66059632; called by muse, mutect2
- CEP63 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777174766, COSV59674760; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 70/188 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- RB1 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 41/55 reads (75%) | catalogued as rs121913304, CM942039, COSV57296489; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs199660234, COSV55458205; ClinVar: likely pathogenic; called by muse, varscan2
- ABCB11 | c.3550C>T p.P1184S | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1370641207, COSV55598990; called by muse, mutect2, varscan2
- ABLIM1 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99522729; called by muse, mutect2, varscan2
- ABO | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101506004; called by muse, mutect2, varscan2
- ACSM2B | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV61659667; called by muse, mutect2, varscan2
- ACTRT3 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57755189; called by muse, mutect2, varscan2
- ADAMTS3 | c.2122G>C p.D708H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54400555; called by muse, mutect2, varscan2
- ADGRB3 | c.3598C>T p.L1200F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV53257680; called by muse, mutect2, varscan2
- ADGRF5 | c.3608G>A p.G1203E | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51939073; called by muse, mutect2, varscan2
- ADH1C | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV72624839; called by muse, mutect2
- AGO4 | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV64618396; called by muse, mutect2, varscan2
- AGTR2 | c.209G>A p.C70Y | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV64156973; called by muse, mutect2, varscan2
- AHCTF1 | c.421C>T p.L141F (on ENST00000366508; = p.L115F on NM_015446.5) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745839202, COSV58254264; called by muse, mutect2, varscan2
- ALOX12 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV52351634; called by muse, mutect2, varscan2
- ANKRD11 | c.7465C>T p.P2489S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56360583; called by muse, mutect2, varscan2
- ANKRD45 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV60962375; called by muse, mutect2, varscan2
- AOC3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53828500; called by muse, mutect2, varscan2
- AOX1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101022234; called by muse, mutect2, varscan2
- AOX1 | c.341G>A p.C114Y | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65983683; called by muse, mutect2, varscan2
- AP1B1 | c.2371G>A p.V791M | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.398); catalogued as COSV58022794; called by muse, mutect2, varscan2
- APOB | c.4549G>A p.E1517K | Missense Mutation (SNP) | VAF 95/448 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV51949514; called by muse, mutect2, varscan2
- ARHGAP11B | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143705474; called by muse, mutect2, varscan2
- ARHGAP25 | c.1786G>A p.E596K (on ENST00000409202 / NM_001007231.3; = p.E588K on NM_014882.3) | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV54907697; called by muse, mutect2, varscan2
- ARHGEF12 | c.3566C>T p.S1189L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.036); catalogued as COSV63106999; called by muse, mutect2, varscan2
- ARPP21 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.542); catalogued as rs1413562397, COSV51806672; called by muse, mutect2, varscan2
- ATG9B | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV52509541; called by muse, varscan2
- ATP13A4 | c.2876C>T p.P959L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as rs947206470, COSV61321848; called by muse, mutect2, varscan2
- ATP6V1C2 | c.1016G>A p.W339* (on ENST00000272238 / NM_001039362.2; = p.W293* on NM_144583.4) | Nonsense Mutation (SNP) | VAF 50/103 reads (49%) | catalogued as COSV55353015; called by muse, mutect2, varscan2
- BCAS2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV65767761; called by muse, mutect2, varscan2
- BCO1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs535639302, COSV50728006; called by muse, mutect2, varscan2
- BEGAIN | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as COSV100767026; called by muse, mutect2, varscan2
- BEGAIN | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs751826296, COSV100767027; called by muse, varscan2
- BIN1 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs781746027, COSV52121486; called by muse, mutect2, varscan2
- BRAT1 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV61394720; called by muse, mutect2, varscan2
- BTN1A1 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV55069320; called by muse, mutect2, varscan2
- C1orf127 | c.619G>T p.G207* | Nonsense Mutation (SNP) | VAF 42/124 reads (34%) | catalogued as COSV65438708; called by muse, mutect2, varscan2
- C1orf94 | c.1008G>A p.M336I (on ENST00000488417 / NM_001134734.2; = p.M146I on NM_032884.5) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs747441377, COSV64915433; called by muse, mutect2, varscan2
- CABP7 | c.110-1G>A p.X37_splice | Splice Site (SNP) | VAF 59/236 reads (25%) | catalogued as COSV53364098; called by muse, mutect2, varscan2
- CACNA1A | c.3948G>A p.W1316* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as rs267605297, COSV64213716; called by muse, mutect2, varscan2
- CACNA1A | c.3947G>A p.W1316* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100802859, COSV64210319; called by muse, mutect2, varscan2
- CACNA1D | c.6259G>A p.E2087K (on ENST00000350061 / NM_001128840.3; = p.E2107K on NM_000720.4) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs762059527, COSV55436089, COSV55439012; called by muse, mutect2, varscan2
- CAND1 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as COSV73389764; called by muse, mutect2, varscan2
- CASS4 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV100824492, COSV64388151; called by muse, mutect2, varscan2
- CCDC144A | c.836G>A p.W279* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100138706; called by muse, mutect2, varscan2
- CCDC38 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 93/163 reads (57%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60184596; called by muse, mutect2, varscan2
- CCDC81 | c.1279G>A p.E427K (on ENST00000445632 / NM_001156474.2; = p.E337K on NM_021827.4) | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as COSV53581092; called by muse, mutect2, varscan2
- CCSER1 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV61460858; called by muse, mutect2, varscan2
- CD226 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs375997671; called by muse, mutect2, varscan2
- CD58 | c.677T>A p.I226N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV101044004; called by muse, mutect2, varscan2
- CD72 | c.894G>A p.W298* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV52409731, COSV99427616; called by muse, mutect2, varscan2
- CD72 | c.893G>A p.W298* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV99427619; called by muse, mutect2, varscan2
- CDC42SE2 | c.55-1G>A p.X19_splice | Splice Site (SNP) | VAF 27/43 reads (63%) | catalogued as COSV64761346; called by muse, mutect2, varscan2
- CDH22 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV64839372; called by muse, mutect2, varscan2
- CDH4 | c.1477G>A p.G493R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as COSV64671417; called by muse, mutect2, varscan2
- CDHR5 | c.1835G>A p.G612E (on ENST00000358353 / NM_001171968.2; = p.G618E on NM_021924.5) | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.259); catalogued as COSV57642998; called by muse, mutect2, varscan2
- CEMIP | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 160/214 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54999195; called by muse, mutect2, varscan2
- CEMIP2 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV65489164; called by muse, mutect2, varscan2
- CEP162 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57623532; called by muse, mutect2, varscan2
- CFAP91 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56341445; called by muse, mutect2, varscan2
- CGNL1 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs200755121; called by muse, mutect2, varscan2
- CHD5 | c.4636G>A p.D1546N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1436290428, COSV52423302; called by muse, mutect2, varscan2
- CHSY3 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as COSV59274179, COSV59286369; called by muse, mutect2, varscan2
- CLEC4F | c.1337A>G p.K446R | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV55481290; called by muse, mutect2, varscan2
- CNGA2 | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 83/120 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61706007; called by muse, mutect2, varscan2
- CNTN4 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs756884036, COSV61879768; called by muse, mutect2, varscan2
- COL19A1 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV59569139; called by muse, mutect2, varscan2
- COL27A1 | c.3481C>T p.P1161S | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV61930125; called by muse, mutect2, varscan2
- COL5A2 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66414170; called by muse, mutect2, varscan2
- COL6A1 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.82); catalogued as COSV62615120, COSV62615259; called by muse, mutect2, varscan2
- COL6A6 | c.6703G>A p.D2235N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.027); catalogued as COSV62035370; called by muse, mutect2, varscan2
- COL9A3 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59655605; called by muse, mutect2, varscan2
- COQ2 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs1310696267, COSV61022171; called by muse, mutect2, varscan2
- CPED1 | c.2540C>T p.P847L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60000337; called by muse, mutect2, varscan2
- CPNE3 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52210014; called by muse, mutect2, varscan2
- CSF2RB | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV53260535; called by muse, mutect2, varscan2
- CSMD2 | c.9682G>A p.E3228K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as rs891390487, COSV53954045; called by muse, mutect2, varscan2
- CSMD3 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 108/165 reads (65%) | catalogued as COSV52092294; called by muse, mutect2, varscan2
- CYP3A43 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs140807333; called by muse, mutect2, varscan2
- CYP3A43 | c.1282G>A p.D428N (on ENST00000354829 / NM_057095.3; = p.D429N on NM_022820.5) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs766579701, COSV55937663; called by muse, mutect2, varscan2
- DEFB110 | c.154A>T p.R52W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64484846; called by muse, mutect2, varscan2
- DGCR6L | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99956939; called by muse, mutect2, varscan2
- DKK2 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 34/112 reads (30%) | catalogued as rs1254069801, COSV53397188, COSV53400080; called by muse, mutect2, varscan2
- DMTF1 | c.1213G>A p.G405S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.351); catalogued as COSV100487516; called by muse, varscan2
- DMTF1 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.648); catalogued as COSV100487517; called by muse, varscan2
- DNAH11 | c.7589A>G p.D2530G | Missense Mutation (SNP) | VAF 103/179 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as rs778427764, COSV60950281, COSV60954707; called by muse, mutect2, varscan2
- DNAH17 | c.10861G>A p.E3621K | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67760241; called by muse, mutect2, varscan2
- DNAH3 | c.10675G>A p.G3559S | Missense Mutation (SNP) | VAF 73/148 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54546176; called by muse, mutect2, varscan2
- DNAH3 | c.10405G>A p.G3469R | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.958); catalogued as rs1252912231, COSV54546198, COSV99765477; called by muse, mutect2, varscan2
- DNAH3 | c.4096C>T p.Q1366* | Nonsense Mutation (SNP) | VAF 68/150 reads (45%) | catalogued as COSV54523669; called by muse, mutect2, varscan2
- DNAH8 | c.11287C>T p.L3763F | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV59463071; called by muse, mutect2, varscan2
- DNAH9 | c.4417G>A p.E1473K | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764728846, COSV52372375; called by muse, mutect2, varscan2
- DNAJC22 | c.881A>T p.H294L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV67712811; called by muse, mutect2, varscan2
- DNAJC7 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.05); catalogued as COSV57268785, COSV57270166; called by muse, mutect2, varscan2
- DNMBP | c.3836C>T p.S1279F | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV60631805; called by muse, mutect2, varscan2
- DOP1A | c.5537C>T p.T1846I | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV52716659; called by muse, mutect2, varscan2
- DPY19L3 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1026812550, COSV100639311; called by muse, mutect2, varscan2
- DSP | c.4199G>A p.R1400Q | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.14); catalogued as rs748109826, COSV65790940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUOX1 | c.1607C>T p.T536I | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV58483623; called by muse, mutect2, varscan2
- DYNAP | c.251G>A p.G84E (on ENST00000321600; = p.G58E on NM_173629.3) | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV58666881; called by muse, mutect2, varscan2
- DYSF | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs773703042, COSV50379416, COSV99245260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EEF1B2 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1471173969, COSV99261476; called by muse, mutect2, varscan2
- EFCAB13 | c.151T>A p.S51T | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); catalogued as COSV58952028; called by muse, mutect2, varscan2
- EFCAB14 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as rs1399566659, COSV64238193; called by muse, mutect2
- ERBB2 | c.2977G>A p.D993N | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV54080757; called by muse, mutect2, varscan2
- EVPL | c.4897C>T p.Q1633* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as rs1417263445, COSV101440972; called by muse, mutect2, varscan2
- EXOC6 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 106/193 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53321360; called by muse, mutect2, varscan2
- FAM169A | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT tolerated (0.48); PolyPhen benign (0.085); catalogued as COSV63064106; called by muse, mutect2, varscan2
- FCAR | c.597G>C p.R199S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV62031255, COSV62031585; called by muse, mutect2
- FCHO2 | c.915G>A p.V305= | Splice Region (SNP) | VAF 9/16 reads (56%) | catalogued as COSV55111189; called by muse, mutect2, varscan2
- FER1L6 | c.2878C>T p.P960S | Missense Mutation (SNP) | VAF 136/226 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.205); catalogued as COSV67552380, COSV67552764; called by mutect2, varscan2
- FETUB | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54004660, COSV54006777; called by muse, mutect2, varscan2
- FOXK2 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.415); catalogued as rs541799688, COSV58882442; called by muse, mutect2, varscan2
- FRMPD4 | c.3830A>T p.E1277V | Missense Mutation (SNP) | VAF 117/146 reads (80%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.332); catalogued as COSV66211300; called by muse, mutect2, varscan2
- FYN | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as COSV57612610, COSV57617681, COSV57618360; called by muse, mutect2, varscan2
- GABRP | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54665306; called by muse, mutect2, varscan2
- GIT1 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV56403849; called by muse, mutect2, varscan2
- GLI2 | c.2315C>T p.S772L (on ENST00000361492 / NM_001374353.1; = p.S789L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.71); PolyPhen benign (0.077); catalogued as rs1374131711, COSV58050028; called by muse, mutect2, varscan2
- HDLBP | c.1498C>T p.L500F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV60500171; called by muse, mutect2, varscan2
- HEATR5B | c.4541C>T p.P1514L | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV51858114; called by muse, mutect2, varscan2
- HERC2 | c.13115C>T p.S4372L | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs371676185; called by muse, mutect2, varscan2
- HERPUD2 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs1411031682, COSV60945274, COSV60946948; called by muse, mutect2, varscan2
- HMGXB4 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1355271905, COSV53335742; called by muse, mutect2, varscan2
- HOMER2 | c.437G>A p.G146E (on ENST00000304231 / NM_199330.3; = p.G135E on NM_004839.4) | Missense Mutation (SNP) | VAF 150/213 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100420613; called by muse, mutect2, varscan2
- HOMER2 | c.436G>A p.G146R (on ENST00000304231 / NM_199330.3; = p.G135R on NM_004839.4) | Missense Mutation (SNP) | VAF 153/214 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1487002849, COSV100420615; called by muse, mutect2, varscan2
- HRNR | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 149/277 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs765957331, COSV100913936; called by muse, mutect2, varscan2
- IGDCC4 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV61538992; called by muse, mutect2, varscan2
- IL36RN | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61010931; called by muse, mutect2, varscan2
- IQSEC3 | c.2390A>G p.N797S (on ENST00000538872 / NM_001170738.2; = p.N494S on NM_015232.1) | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.193); catalogued as COSV58290005; called by muse, mutect2, varscan2
- IRF6 | c.1182C>T p.V394= | Splice Region (SNP) | VAF 38/72 reads (53%) | catalogued as COSV54214972; called by muse, mutect2, varscan2
- IRF7 | c.1501C>T p.L501F (on ENST00000397566; = p.L488F on NM_001572.5) | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52761726; called by muse, mutect2, varscan2
- ITGB1 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 66/98 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV56486296; called by muse, mutect2, varscan2
- KAT2B | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV55433673; called by muse, mutect2, varscan2
- KCNMA1 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV54268725; called by muse, mutect2, varscan2
- KCNT2 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54089998; called by muse, mutect2, varscan2
- KDM5B | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as COSV99351404; called by muse, mutect2, varscan2
- KIAA1109 | c.8714C>T p.P2905L | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52689337; called by muse, mutect2, varscan2
- KIAA1549 | c.5008G>A p.A1670T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.643); catalogued as rs372568067; called by muse, mutect2, varscan2
- KIF1A | c.4973G>A p.G1658D (on ENST00000320389 / NM_001379639.1; = p.G1650D on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57499617; called by muse, mutect2, varscan2
- KIF21A | c.4456G>A p.G1486R (on ENST00000361418 / NM_001378440.1; = p.G1473R on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62777016; called by muse, mutect2
- KLHL36 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV50722955; called by muse, mutect2, varscan2
- KRT17 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs1292924721, COSV60861760; called by muse, mutect2, varscan2
- KRT36 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.76); catalogued as COSV100057748; called by muse, mutect2, varscan2
- KRT5 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs182482982, COSV52863072; called by muse, mutect2, varscan2
- LGI4 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV59534802, COSV59535098; called by muse, mutect2, varscan2
- LPL | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 83/99 reads (84%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as COSV100255814; called by muse, mutect2, varscan2
- LRIT3 | c.1160G>A p.W387* | Nonsense Mutation (SNP) | VAF 77/170 reads (45%) | catalogued as COSV59987356; called by muse, mutect2, varscan2
- LRP1B | c.12700G>A p.D4234N | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as rs867914094, COSV67244438; called by muse, mutect2, varscan2
- LRRFIP1 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs201221434; called by muse, mutect2, varscan2
- LUC7L | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53458072; called by muse, mutect2, varscan2
- LY9 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV54437206; called by muse, mutect2, varscan2
- MAB21L3 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as COSV65674420; called by muse, mutect2, varscan2
- MAGEA10 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54883060; called by muse, mutect2, varscan2
- MAGEB3 | c.464A>T p.K155I | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV64397664; called by muse, mutect2, varscan2
- MAGEC1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53570262; called by muse, mutect2, varscan2
- MAP3K21 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs555966831, COSV64042255; called by muse, mutect2, varscan2
- MAP4K4 | c.2780C>T p.S927F (on ENST00000347699 / NM_001242559.2; = p.S845F on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV56339333; called by muse, mutect2, varscan2
- MCM3AP | c.4054C>T p.P1352S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1177722649, COSV99387519; called by muse, mutect2, varscan2
- MDM4 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV65798263; called by muse, mutect2, varscan2
- MEIS2 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 136/224 reads (61%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV54943513; called by muse, mutect2, varscan2
- MS4A10 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV57633934; called by muse, mutect2, varscan2
- MS4A10 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs141894920; called by muse, mutect2, varscan2
- MUC16 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67477137; called by muse, mutect2, varscan2
- MUC21 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.882); catalogued as rs796267398, COSV100888926; called by muse, mutect2, varscan2
- MUC21 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.32); catalogued as COSV100888927; called by muse, mutect2, varscan2
- MUC4 | c.13849G>A p.G4617R (on ENST00000463781 / NM_018406.7; = p.G381R on NM_004532.6) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV57799886; called by muse, mutect2, varscan2
- MUSK | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs773818596, COSV51878062; called by muse, mutect2, varscan2
- MYH11 | c.3291C>T p.A1097= | Splice Region (SNP) | VAF 28/64 reads (44%) | catalogued as rs147605116; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MYH15 | c.4355C>T p.A1452V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV99844313; called by muse, mutect2, varscan2
- MYH2 | c.4781G>A p.R1594K | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV55442365, COSV55446942; called by muse, mutect2, varscan2
- MYH4 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV55124782; called by muse, mutect2, varscan2
- MYT1 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs374805913; called by muse, mutect2, varscan2
- N4BP1 | c.1912T>C p.S638P | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52212892; called by muse, mutect2, varscan2
- NBEA | c.6515C>T p.S2172F | Missense Mutation (SNP) | VAF 96/122 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100084223; called by muse, mutect2, varscan2
- NBPF11 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.587); catalogued as rs1446819789; called by mutect2, varscan2
- NCAPD2 | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 118/306 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754648578, COSV59702001; called by muse, mutect2, varscan2
- NCR1 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as rs774857066, COSV52557516; called by muse, mutect2, varscan2
- NEK5 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62881619; called by muse, mutect2, varscan2
- NFATC1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV53701987; called by mutect2, varscan2
- NLRP5 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 105/317 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537471101, COSV66762321; called by muse, mutect2, varscan2
- NOL3 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV50459199; called by muse, mutect2, varscan2
- NPHP4 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as rs1430741326, COSV65397303; called by muse, mutect2, varscan2
- NRXN3 | c.1729G>A p.E577K (on ENST00000335750 / NM_001330195.2; = p.E204K on NM_004796.6) | Missense Mutation (SNP) | VAF 63/96 reads (66%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV59798386; called by muse, mutect2, varscan2
- NXN | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV61099790; called by muse, mutect2, varscan2
- OGDHL | c.2074C>T p.H692Y | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV65104279; called by muse, mutect2, varscan2
- OR10W1 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs915513623, COSV67720332; called by muse, mutect2, varscan2
- OR13F1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1050418864, COSV58251968, COSV58252528; called by muse, mutect2, varscan2
- OR1M1 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101447532, COSV70037474; called by muse, mutect2, varscan2
- OR2G3 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 120/455 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60682777, COSV60682889; called by muse, mutect2, varscan2
- OR2T12 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as COSV100527998; called by muse, mutect2, varscan2
- OR4D1 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV52125895; called by muse, mutect2, varscan2
- OR5B3 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV58678151; called by muse, mutect2, varscan2
- OR6M1 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV58434659; called by muse, mutect2, varscan2
- PAPPA | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV60290434; called by muse, mutect2, varscan2
- PCDHGA2 | c.1309C>T p.H437Y | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.022); catalogued as COSV54016678; called by muse, mutect2, varscan2
- PCDHGB3 | c.1652T>C p.L551S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV54016692; called by muse, mutect2, varscan2
- PCK1 | c.909G>A p.W303* | Nonsense Mutation (SNP) | VAF 50/134 reads (37%) | catalogued as rs759511459, COSV60130592; called by muse, mutect2, varscan2
- PCLO | c.9451G>A p.E3151K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.439); catalogued as COSV61660555; called by muse, mutect2, varscan2
- PIK3C2G | c.3601G>A p.E1201K (on ENST00000676171; = p.E1160K on NM_004570.5) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV56796183; called by muse, mutect2
- PILRB | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100167213; called by muse, mutect2, varscan2
- PITPNM2 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140068156, COSV54907423; called by muse, mutect2, varscan2
- PKD1 | c.3854G>A p.R1285Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs368189158; called by muse, mutect2, varscan2
- PKHD1L1 | c.2933G>A p.G978E | Missense Mutation (SNP) | VAF 96/167 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65751068; called by muse, mutect2, varscan2
- PKHD1L1 | c.11069G>A p.G3690D | Missense Mutation (SNP) | VAF 61/98 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1563621835, COSV65751074; called by muse, mutect2, varscan2
- PLA2G4C | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV62785156; called by muse, mutect2, varscan2
- PLAAT1 | c.343A>T p.N115Y (on ENST00000650797; = p.N10Y on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV53233089; called by muse, mutect2
- PLAT | c.95G>C p.R32T | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1390184489, COSV54277633; called by muse, mutect2, varscan2
- PLCB1 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs867281730, COSV62042382; called by muse, mutect2, varscan2
- PLCH2 | c.3968C>T p.P1323L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs758895302, COSV53948569; called by muse, mutect2, varscan2
- PLEKHJ1 | c.416_418del p.E139del | In Frame Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs769133845; called by pindel, varscan2
- PNPLA7 | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | catalogued as COSV53005520; called by muse, varscan2
- PPP1R26 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV63357143; called by muse, mutect2, varscan2
- PPP2CA | c.659T>C p.F220S | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51539030; called by muse, mutect2, varscan2
- PPP3R2 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV62457473; called by muse, mutect2, varscan2
- PPP6C | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV65207221; called by muse, mutect2, varscan2
- PPT2 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 207/665 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV52999483; called by muse, mutect2, varscan2
- PRMT9 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV59361164; called by muse, mutect2, varscan2
- PRRC2A | c.332T>G p.L111R | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV63224983; called by muse, mutect2
- PSG8 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 120/383 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV60614993; called by muse, mutect2, varscan2
- PSMD4 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as rs1224936911, COSV100924694; called by muse, mutect2, varscan2
- PSMD4 | c.657C>T p.A219= | Splice Region (SNP) | VAF 35/83 reads (42%) | catalogued as COSV100924695; called by muse, mutect2, varscan2
- PUS7 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.625); catalogued as COSV62678057; called by muse, mutect2, varscan2
- PYGB | c.2447G>A p.R816Q | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1464344437, COSV53822268; called by muse, mutect2, varscan2
- RALBP1 | c.1082T>A p.F361Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50038384; called by muse, mutect2, varscan2
- RANBP2 | c.7877C>T p.S2626F | Missense Mutation (SNP) | VAF 102/207 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV51707238; called by muse, mutect2, varscan2
- RASAL1 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 177/302 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487918389, COSV55659237, COSV99921512; called by muse, mutect2, varscan2
- RASAL1 | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV55659245; called by muse, mutect2, varscan2
- RBFOX1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1567934913, COSV60978015; called by muse, mutect2, varscan2
- RIMS2 | c.883G>A p.D295N (on ENST00000666250 / NM_001348490.2; = p.D103N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.895); catalogued as rs1469042326, COSV51657475; called by muse, mutect2, varscan2
- RO60 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66474775; called by muse, mutect2
- RO60 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1176157193, COSV66474784; called by muse, mutect2
- RP1L1 | c.1868G>A p.G623E | Missense Mutation (SNP) | VAF 90/116 reads (78%) | SIFT tolerated (0.26); PolyPhen benign (0.112); catalogued as COSV101223597, COSV66759368; called by muse, mutect2, varscan2
- RPGRIP1 | c.2870A>G p.E957G | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV52856049; called by muse, mutect2, varscan2
- RPL10 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 61/80 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV50011008; called by muse, mutect2, varscan2
- RPL11 | c.173C>T p.S58F (on ENST00000374550 / NM_001199802.1; = p.S59F on NM_000975.5) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV65778945; called by muse, mutect2, varscan2
- RPRD2 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 120/260 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64822929, COSV64823398; called by muse, mutect2, varscan2
- RTCB | c.94-1G>A p.X32_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV53280208; called by muse, mutect2, varscan2
- SAP130 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.007); catalogued as COSV99385311; called by muse, mutect2, varscan2
- SATB1 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV58668220, COSV58672213; called by muse, mutect2, varscan2
- SCD | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as COSV100948935; called by muse, mutect2, varscan2
- SCD | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100948936; called by muse, mutect2, varscan2
- SDK1 | c.5354G>A p.G1785E | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368890852, COSV67385810; called by muse, mutect2, varscan2
- SEC16B | c.3050T>G p.L1017R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV57629509; called by muse, mutect2, varscan2
- SEC31B | c.3104C>T p.P1035L | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1306538263, COSV100947472; called by muse, mutect2, varscan2
- SEC31B | c.3103C>T p.P1035S | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV64844081; called by muse, mutect2, varscan2
- SEMA4C | c.2431G>A p.D811N | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.631); catalogued as COSV59689671; called by muse, mutect2, varscan2
- SERPINB11 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.961); catalogued as COSV66956993; called by muse, mutect2, varscan2
- SERPINB3 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52193727; called by muse, mutect2, varscan2
- SETD2 | c.4003C>T p.R1335C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1216047088, COSV57448285; called by muse, mutect2, varscan2
- SEZ6L | c.2191G>A p.G731R | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50680944; called by muse, mutect2, varscan2
- SH3TC1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as rs1478666472, COSV55288922; called by muse, mutect2, varscan2
- SIGLEC1 | c.3461C>T p.P1154L | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV99170880; called by muse, mutect2, varscan2
- SIGLEC1 | c.3460C>T p.P1154S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV52468988, COSV99170896; called by muse, mutect2, varscan2
- SIGLEC10 | c.665A>G p.K222R | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.067); catalogued as COSV59485970; called by muse, mutect2, varscan2
- SIGLECL1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV57064446; called by muse, mutect2, varscan2
- SLC12A6 | c.980T>A p.V327D (on ENST00000354181 / NM_001365088.1; = p.V276D on NM_005135.2) | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV51630828; called by muse, mutect2, varscan2
- SLC26A9 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs375835575; called by muse, mutect2, varscan2
- SLC37A1 | c.565A>G p.R189G | Missense Mutation (SNP) | VAF 78/233 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100721840; called by muse, mutect2, varscan2
- SLC37A1 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100721578, COSV100721842; called by muse, mutect2, varscan2
- SLC38A1 | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476685725, COSV101284281; called by muse, mutect2, varscan2
- SLC38A1 | c.1265-1G>A p.X422_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | catalogued as COSV101284283; called by muse, mutect2, varscan2
- SLC45A4 | c.1301G>A p.G434E (on ENST00000517878 / NM_001286646.2; = p.G383E on NM_001080431.2) | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50172944; called by muse, mutect2, varscan2
- SLC4A10 | c.1310G>A p.R437Q (on ENST00000446997 / NM_001354461.2; = p.R407Q on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55770206, COSV55774465; called by muse, mutect2, varscan2
- SLC4A11 | c.2595G>A p.M865I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV66263645; called by muse, mutect2, varscan2
- SLCO4C1 | c.2050G>A p.G684R | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.396); catalogued as COSV60515160, COSV60515406; called by muse, mutect2, varscan2
- SMC6 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV61176210, COSV61177805; called by muse, mutect2
- SOX9 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV55424239, COSV55424784; called by muse, mutect2, varscan2
- SP7 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV100382132, COSV58191918; called by muse, mutect2, varscan2
- SPANXN2 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 166/222 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV65129304; called by muse, varscan2
- SPICE1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs1234230932, COSV55619153, COSV55624185; called by muse, mutect2, varscan2
- SPRR3 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as rs745418082, COSV54880382, COSV99040043; called by muse, varscan2
- SREBF1 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765844815, COSV55419420; called by muse, mutect2, varscan2
- SRPRA | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 77/117 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV55008661; called by muse, mutect2, varscan2
- SVEP1 | c.10498G>A p.E3500K | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52843175; called by muse, mutect2, varscan2
- SWSAP1 | c.626C>T p.P209L (on ENST00000312423; = p.P230L on NM_175871.4) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55801090, COSV99710004; called by muse, mutect2, varscan2
- TAB1 | c.770T>G p.L257R | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.741); catalogued as COSV53372913; called by muse, mutect2, varscan2
- TBC1D2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs374420605; called by muse, mutect2, varscan2
- TENT5D | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57638844; called by muse, mutect2, varscan2
- TF | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV53923543; called by muse, mutect2, varscan2
- THSD7A | c.4907C>T p.P1636L | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV68472165; called by muse, mutect2, varscan2
- TJP2 | c.3139C>T p.R1047W | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs148629740; called by muse, mutect2, varscan2
- TKFC | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs34035740; called by muse, mutect2, varscan2
- TMEM121B | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV58898388; called by muse, mutect2
- TMEM184C | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV56854583; called by muse, mutect2, varscan2
- TMEM52 | c.348C>T p.T116= | Splice Region (SNP) | VAF 24/89 reads (27%) | catalogued as COSV57070768; called by muse, mutect2, varscan2
- TMPRSS6 | c.1951C>T p.H651Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60983092; called by muse, mutect2, varscan2
- TNNT3 | c.479C>T p.S160F (on ENST00000397301 / NM_001367846.1; = p.S149F on NM_006757.4) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53489223; called by muse, mutect2, varscan2
- TNR | c.1038G>A p.W346* | Nonsense Mutation (SNP) | VAF 96/211 reads (45%) | catalogued as COSV54908981, COSV99688911; called by muse, mutect2, varscan2
- TNS3 | c.150G>A p.L50= | Splice Region (SNP) | VAF 28/45 reads (62%) | catalogued as COSV60797857; called by muse, mutect2, varscan2
- TOR1AIP2 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as COSV100857540; called by muse, mutect2, varscan2
- TOR1AIP2 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.034); catalogued as COSV100857541; called by muse, mutect2, varscan2
- TP63 | c.1190A>G p.D397G | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53218754; called by muse, mutect2, varscan2
- TRERF1 | c.3197C>T p.S1066L | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs529112775, COSV61677199; called by muse, mutect2, varscan2
- TRERF1 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); catalogued as COSV100551673; called by muse, mutect2, varscan2
- TRERF1 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.031); catalogued as COSV100551679; called by muse, mutect2, varscan2
- TSGA10 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV61825362; called by muse, mutect2, varscan2
- TXNL1 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 56/169 reads (33%) | catalogued as rs965035395, COSV54178870; called by muse, mutect2, varscan2
- UBXN10 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1252753403, COSV66772573; called by muse, mutect2, varscan2
- UGT2B4 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59319947, COSV59320070; called by muse, mutect2, varscan2
- UNC13C | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 77/110 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs746269797, COSV52862396; called by muse, mutect2, varscan2
- USP32 | c.3212C>T p.P1071L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV100342869; called by muse, mutect2, varscan2
- USP32 | c.3211C>A p.P1071T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100342872; called by muse, mutect2, varscan2
- VCAM1 | c.104A>C p.Y35S | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV54121511; called by muse, mutect2, varscan2
- VN1R4 | c.322A>C p.T108P | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100237601; called by mutect2, varscan2
- VPS13A | c.3431T>G p.V1144G | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.418); catalogued as COSV62437380; called by muse, mutect2, varscan2
- VPS13D | c.4184C>T p.P1395L | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV50673710; called by muse, mutect2, varscan2
- WDR17 | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54581936; called by muse, mutect2, varscan2
- WDR72 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV64752793; called by muse, mutect2, varscan2
- WWC1 | c.2330C>T p.S777L | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.65); PolyPhen benign (0.146); catalogued as rs368353585, COSV54656652; called by muse, mutect2, varscan2
- WWC1 | c.3326C>T p.S1109F | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV54657468; called by muse, mutect2, varscan2
- XPO5 | c.2966C>T p.P989L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1240241022, COSV54834198; called by muse, varscan2
- XPO5 | c.2965C>T p.P989S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV99541425; called by muse, varscan2
- ZAN | c.7780C>T p.L2594F | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV100770332, COSV61815842; called by muse, mutect2, varscan2
- ZBTB12 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 121/463 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV99062662; called by muse, mutect2, varscan2
- ZDHHC6 | c.1117C>T p.L373F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.059); catalogued as COSV61128906, COSV61133155; called by muse, mutect2, varscan2
- ZEB1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV58052739; called by muse, mutect2, varscan2
- ZNF334 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV61619904; called by muse, mutect2, varscan2
- ZNF536 | c.3409G>A p.G1137R | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.216); catalogued as COSV62832684; called by muse, mutect2, varscan2
- ZNF71 | c.1321G>A p.G441S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1295728444, COSV100046304; called by muse, mutect2, varscan2
- ZNF71 | c.1322G>A p.G441D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV60149163, COSV60150787; called by muse, mutect2, varscan2
- ZNF804A | c.871G>C p.V291L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56443173, COSV56467708; called by muse, mutect2, varscan2
- ZNF835 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs765467237, COSV73379714; called by muse, mutect2
- CENPB | c.205_222del p.N69_Y74del | In Frame Del (DEL) | VAF 20/83 reads (24%) | called by mutect2, pindel, varscan2
- FOLH1 | c.2114del p.F705Sfs*24 | Frame Shift Del (DEL) | VAF 38/97 reads (39%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.2483C>T p.S828F | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- GDF2 | c.1191A>T p.K397N | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GOLGA2 | c.1731_1751del p.K578_E584del | In Frame Del (DEL) | VAF 38/156 reads (24%) | called by mutect2, pindel, varscan2
- ICAM1 | c.1041_1066del p.Q348Pfs*96 | Frame Shift Del (DEL) | VAF 31/131 reads (24%) | called by mutect2, pindel
- PCDHGB5 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBMXL1 | c.1038_1061del p.L348_G355del | In Frame Del (DEL) | VAF 48/251 reads (19%) | called by pindel, varscan2
- TMEM225 | c.631del p.S211Pfs*2 | Frame Shift Del (DEL) | VAF 36/81 reads (44%) | called by mutect2, pindel, varscan2
- TRAV1-1 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 81/128 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VARS1 | c.80_104del p.A27Efs*73 | Frame Shift Del (DEL) | VAF 79/368 reads (21%) | called by mutect2, varscan2
- ABCA7 | c.5811C>T p.A1937= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs1348301970, COSV54036256; called by muse, mutect2, varscan2
- ABLIM1 | c.912C>T p.Y304= | Silent (SNP) | VAF 82/217 reads (38%) | catalogued as COSV99522731; called by muse, mutect2, varscan2
- ADCY3 | c.1851C>T p.D617= | Silent (SNP) | VAF 63/125 reads (50%) | catalogued as COSV53167422; called by muse, mutect2, varscan2
- ADGRG6 | c.1617C>T p.I539= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV51599920; called by muse, mutect2, varscan2
- ADGRL2 | c.3198A>C p.A1066= (on ENST00000370717 / NM_001366005.1; = p.A1053= on NM_012302.4) | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2
- AGPAT3 | c.540C>T p.F180= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs1350334869, COSV52373587; called by muse, mutect2, varscan2
- AKAP11 | c.5439G>A p.T1813= | Silent (SNP) | VAF 74/92 reads (80%) | catalogued as rs372892641, COSV50298663; called by muse, mutect2, varscan2
- AKR1B1 | c.615C>T p.I205= | Silent (SNP) | VAF 111/204 reads (54%) | catalogued as rs188664638, COSV53647958; called by muse, mutect2, varscan2
- AOX1 | c.141A>T p.G47= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV101022235; called by muse, mutect2, varscan2
- ARHGAP11A | c.1947G>A p.L649= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as rs775597191, COSV55708211; called by muse, mutect2, varscan2
- ARSA | c.423G>A p.Q141= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV53351138; called by muse, mutect2, varscan2
- ATAD5 | c.315C>T p.F105= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV58978171; called by muse, mutect2, varscan2
- ATF6 | c.1218C>T p.N406= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs771652428, COSV63409753; called by muse, mutect2, varscan2
- ATG2A | c.1858C>T p.L620= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV101034802; called by muse, mutect2, varscan2
- ATG2A | c.1857C>T p.G619= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV101034804; called by muse, mutect2, varscan2
- ATP2B2 | c.2715C>T p.I905= (on ENST00000352432; = p.I871= on NM_001683.5) | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as rs1268337252, COSV59506069; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1680C>T p.I560= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as COSV57751799; called by muse, mutect2, varscan2
- ATP8A1 | c.3471G>A p.T1157= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs756560495, COSV52528078; called by muse, mutect2, varscan2
- ATP8B3 | c.3276C>G p.V1092= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV59547718; called by muse, mutect2, varscan2
- B4GALNT3 | c.1435C>T p.L479= | Silent (SNP) | VAF 60/173 reads (35%) | catalogued as COSV56757171; called by muse, mutect2, varscan2
- BIRC6 | c.1860T>G p.S620= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV70204552; called by muse, mutect2, varscan2
- C7orf26 | c.1242G>A p.L414= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV60420242; called by muse, mutect2, varscan2
- CABYR | c.234G>A p.K78= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV59110313, COSV59112424; called by muse, mutect2, varscan2
- CAP2 | c.264C>T p.F88= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as COSV57736201; called by muse, mutect2, varscan2
- CBL | c.852C>T p.F284= | Silent (SNP) | VAF 38/65 reads (58%) | catalogued as rs745855639, COSV50657740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC136 | c.361C>T p.L121= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV52804060; called by muse, mutect2
- CD58 | c.678T>A p.I226= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV101044003; called by muse, mutect2, varscan2
- CHD6 | c.2569C>T p.L857= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV58561573; called by muse, mutect2, varscan2
- CLASRP | c.786C>T p.Y262= | Silent (SNP) | VAF 179/546 reads (33%) | catalogued as COSV55518731; called by muse, mutect2, varscan2
- CLDN14 | c.372C>T p.L124= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as rs1395409995, COSV59773643, COSV59776987; called by muse, mutect2, varscan2
- CLDN15 | c.441C>T p.F147= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV57659652; called by muse, mutect2, varscan2
- CNOT1 | c.204C>T p.F68= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV57778879; called by muse, mutect2, varscan2
- COL11A2 | c.3147C>T p.V1049= (on ENST00000341947 / NM_080680.3; = p.V942= on NM_080679.2) | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV59501777; called by muse, mutect2, varscan2
- CRACD | c.2565C>T p.S855= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV51716245; called by muse, mutect2, varscan2
- CSMD2 | c.7833G>A p.E2611= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV53954072; called by muse, mutect2, varscan2
- CUL9 | c.2601G>A p.A867= | Silent (SNP) | VAF 82/308 reads (27%) | catalogued as rs567375546, COSV52733667; called by muse, mutect2, varscan2
- DLC1 | c.1818C>T p.H606= (on ENST00000276297 / NM_001348081.2; = p.H169= on NM_006094.5) | Silent (SNP) | VAF 78/224 reads (35%) | catalogued as rs561597944, COSV52324158; called by muse, mutect2, varscan2
- DMBT1 | c.7215G>A p.V2405= (on ENST00000338354 / NM_001377530.1; = p.V1648= on NM_004406.3) | Silent (SNP) | VAF 59/127 reads (46%) | catalogued as COSV57558486; called by muse, mutect2, varscan2
- DMP1 | c.1335G>A p.E445= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs1238855867, COSV56821913; called by muse, mutect2, varscan2
- DMXL1 | c.3555C>T p.L1185= | Silent (SNP) | VAF 58/88 reads (66%) | catalogued as COSV60719562; called by muse, mutect2, varscan2
- DNAH3 | c.5422C>T p.L1808= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV54546222; called by muse, mutect2, varscan2
- DNAH5 | c.1575C>T p.F525= | Silent (SNP) | VAF 48/78 reads (62%) | catalogued as rs755393698, COSV54214934; called by muse, mutect2, varscan2
- DNMBP | c.3303G>A p.R1101= | Silent (SNP) | VAF 66/154 reads (43%) | catalogued as COSV60631824; called by muse, mutect2, varscan2
- DPY19L3 | c.1959C>T p.L653= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs536118263, COSV100639310; called by muse, mutect2, varscan2
- DSCAM | c.1236C>A p.A412= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV68034385; called by muse, mutect2, varscan2
- DUOX1 | c.1608C>A p.T536= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs1182044942, COSV100368488; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1356G>A p.L452= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs1472025761, COSV56128846; called by muse, mutect2, varscan2
- ECM2 | c.486C>T p.S162= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV60742664; called by muse, mutect2, varscan2
- EEF1B2 | c.24C>T p.S8= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as rs760263486, COSV99261474; called by muse, mutect2, varscan2
- EFNB1 | c.921G>A p.R307= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV52662601; called by muse, mutect2, varscan2
- EPB41L3 | c.2097C>T p.A699= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs140128908, COSV59465390; called by muse, mutect2, varscan2
- EPHA3 | c.399G>A p.V133= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV60723599; called by muse, mutect2, varscan2
- EPOR | c.1063C>T p.L355= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs768821794, COSV99710309; called by muse, mutect2, varscan2
- EPOR | c.1062C>T p.P354= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV99710310; called by muse, mutect2, varscan2
- ETS2 | c.930C>T p.S310= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV62874103; called by muse, mutect2, varscan2
- EVPL | c.4896C>T p.A1632= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV56915032; called by muse, mutect2, varscan2
- FAM110B | c.441C>T p.H147= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs1284308938, COSV64063668; called by muse, mutect2, varscan2
- GIMAP8 | c.597C>T p.P199= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as rs761270896, COSV56233373; called by muse, mutect2, varscan2
- GIMAP8 | c.729G>A p.P243= | Silent (SNP) | VAF 51/188 reads (27%) | catalogued as rs762955793, COSV56233382; called by muse, mutect2, varscan2
- GRB7 | c.546G>A p.R182= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs1477043469, COSV58450514; called by muse, mutect2, varscan2
- GREB1 | c.3600C>T p.P1200= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs529617459, COSV52194935; called by muse, mutect2, varscan2
- GRIN2B | c.528C>T p.F176= | Silent (SNP) | VAF 59/159 reads (37%) | catalogued as COSV74204926; called by muse, mutect2, varscan2
- GSDMA | c.525C>T p.F175= | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- HEATR1 | c.2202G>A p.Q734= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV63982785; called by muse, mutect2, varscan2
- HLCS | c.1470G>A p.P490= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as rs775832153, COSV60792765; called by muse, mutect2, varscan2
- HNRNPU | c.2178G>A p.Q726= (on ENST00000283179; = p.Q788= on NM_004501.3) | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV51693690, COSV99310590; called by muse, mutect2, varscan2
- IL22RA1 | c.651C>T p.C217= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV54630156; called by muse, mutect2, varscan2
- KDM5B | c.888C>T p.P296= | Silent (SNP) | VAF 47/283 reads (17%) | catalogued as rs746018377, COSV99351401; called by muse, mutect2, varscan2
- KIF24 | c.4038G>A p.R1346= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as rs1349580468, COSV52661320; called by muse, mutect2, varscan2
- KIR3DL1 | c.609C>T p.P203= | Silent (SNP) | VAF 88/400 reads (22%) | catalogued as COSV58495322; called by muse, mutect2
- KRT36 | c.114G>A p.R38= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs758955999, COSV100057745; called by muse, mutect2, varscan2
- KRT71 | c.1347C>T p.S449= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV57292645; called by muse, mutect2, varscan2
- LCMT1 | c.903C>T p.F301= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV66726963; called by muse, mutect2, varscan2
- LHX8 | c.468C>T p.V156= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV53959576; called by muse, mutect2, varscan2
- LILRB1 | c.387A>G p.T129= (on ENST00000427581; = p.T93= on NM_006669.6) | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as COSV61121211; called by mutect2, varscan2
- LMBR1 | c.696C>T p.D232= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV62222832; called by muse, mutect2, varscan2
- LRP2 | c.12012C>T p.S4004= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs773085878, COSV55552431; called by muse, mutect2, varscan2
- LRRC18 | c.72C>T p.I24= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as COSV53285621; called by muse, mutect2, varscan2
- LUC7L | c.1038C>T p.P346= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as rs773224045, COSV53460794; called by muse, mutect2, varscan2
- MCM3AP | c.4053C>T p.L1351= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99387521; called by muse, mutect2, varscan2
- MST1 | c.1296C>T p.F432= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs1346263688, COSV56536413; called by muse, mutect2, varscan2
- MYH1 | c.4263G>A p.T1421= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs370946637; called by muse, mutect2, varscan2
- MYH15 | c.4356C>T p.A1452= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs1560331340, COSV99844312; called by muse, mutect2, varscan2
- MYO1H | c.2283G>A p.R761= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs1170930576, COSV60450020; called by muse, mutect2, varscan2
- MYOM3 | c.1053C>T p.F351= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs143871016, COSV58394857; called by muse, mutect2
- MZF1 | c.427C>T p.L143= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs757629894, COSV53043509, COSV99285468; called by muse, mutect2, varscan2
- MZF1 | c.426C>T p.V142= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs201793159, COSV99285469; called by muse, mutect2, varscan2
- NBEA | c.6516C>T p.S2172= | Silent (SNP) | VAF 96/122 reads (79%) | catalogued as COSV100084225; called by muse, mutect2, varscan2
- NFATC1 | c.663T>C p.F221= | Silent (SNP) | VAF 56/110 reads (51%) | catalogued as rs1234467660, COSV99502540; called by mutect2, varscan2
- NLRP9 | c.621G>A p.P207= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs776781826, COSV60467111; called by muse, mutect2, varscan2
- NPY2R | c.264C>T p.F88= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV61528313; called by muse, mutect2, varscan2
- NRSN2 | c.522C>T p.F174= | Silent (SNP) | VAF 56/155 reads (36%) | catalogued as COSV66526910; called by muse, mutect2, varscan2
- OPN4 | c.417G>A p.G139= | Silent (SNP) | VAF 48/82 reads (59%) | catalogued as COSV54119121; called by muse, mutect2, varscan2
- OR14C36 | c.672C>T p.L224= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as rs769618661, COSV58601495, COSV58602585; called by muse, mutect2, varscan2
- OR2AE1 | c.78C>T p.F26= | Silent (SNP) | VAF 60/122 reads (49%) | catalogued as COSV60389693, COSV60391053; called by muse, mutect2, varscan2
- OR2T27 | c.201C>T p.S67= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV61282771; called by muse, mutect2, varscan2
- OR4A47 | c.105G>A p.L35= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV71445115; called by muse, mutect2, varscan2
- OR5R1 | c.801C>T p.S267= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV56573443; called by muse, mutect2, varscan2
- OR6C4 | c.180C>T p.F60= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV67793238; called by muse, mutect2, varscan2
- OR7E24 | c.864G>A p.K288= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs200671636, COSV71702340; called by muse, mutect2, varscan2
- PCDHB16 | c.166T>C p.L56= | Silent (SNP) | VAF 121/168 reads (72%) | catalogued as COSV53369671; called by muse, mutect2, varscan2
- PCK1 | c.1863G>A p.Q621= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV60130604; called by muse, mutect2, varscan2
- PDE1C | c.1371C>T p.T457= | Silent (SNP) | VAF 96/192 reads (50%) | catalogued as rs746436711, COSV58526051; called by muse, mutect2, varscan2
- PDE6B | c.390C>T p.I130= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs755636741, COSV55330112; called by muse, mutect2, varscan2
- PID1 | c.657C>T p.F219= (on ENST00000354069 / NM_001330156.1; = p.F217= on NM_017933.5) | Silent (SNP) | VAF 59/124 reads (48%) | catalogued as COSV62481489; called by muse, mutect2, varscan2
- PIK3C2G | c.3315G>A p.G1105= (on ENST00000676171; = p.G1064= on NM_004570.5) | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV56829213; called by muse, mutect2, varscan2
- PILRB | c.156C>T p.P52= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100167215; called by muse, mutect2, varscan2
- PKHD1L1 | c.8499C>T p.F2833= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV65743502; called by muse, mutect2, varscan2
- PNPLA8 | c.645C>T p.F215= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV57554404; called by muse, mutect2, varscan2
- POLR3A | c.2277C>T p.I759= | Silent (SNP) | VAF 7/8 reads (88%) | catalogued as COSV64931947; called by muse, mutect2, varscan2
- POM121L12 | c.39G>A p.G13= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV68692526; called by muse, mutect2
- PPM1L | c.387G>A p.G129= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV72263389; called by muse, mutect2, varscan2
- PROKR2 | c.954C>T p.V318= | Silent (SNP) | VAF 52/169 reads (31%) | catalogued as rs779358775, COSV54088878; called by muse, mutect2, varscan2
- PRPSAP1 | c.324C>T p.I108= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV61212479; called by muse, mutect2, varscan2
- PSPH | c.603C>T p.I201= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs763944186, COSV51912750; called by muse, mutect2, varscan2
- PTGFR | c.666C>T p.I222= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV66114098, COSV66116413; called by muse, mutect2, varscan2
- PTHLH | c.423G>A p.R141= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV52369252; called by muse, mutect2, varscan2
- PTPRO | c.1176G>A p.G392= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV55508304; called by muse, mutect2, varscan2
- PXDNL | c.1578G>A p.K526= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1276277900, COSV62496852; called by muse, mutect2, varscan2
- QRICH2 | c.1818C>T p.V606= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV53154272, COSV53157212; called by muse, mutect2, varscan2
- RALGAPB | c.1872C>T p.L624= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as rs369787930; called by muse, mutect2, varscan2
- RIMS1 | c.993G>A p.P331= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs760689367, COSV53438472; called by muse, mutect2, varscan2
- RNF183 | c.321C>T p.R107= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV52908201; called by muse, mutect2, varscan2
- RPS16 | c.219G>A p.K73= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs11555712, COSV52239428; called by muse, mutect2, varscan2
- RUFY4 | c.1167G>A p.E389= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV60249141; called by muse, mutect2, varscan2
- SALL3 | c.282C>T p.F94= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV73305846, COSV73306453; called by muse, mutect2, varscan2
- SALL3 | c.2907G>A p.R969= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs761112279, COSV73305964, COSV73306456; called by muse, mutect2, varscan2
- SAP130 | c.855C>T p.I285= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV52102828; called by muse, mutect2, varscan2
- SEC16A | c.6228G>A p.T2076= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs776101479, COSV51538255; called by muse, mutect2, varscan2
- SEL1L2 | c.75A>G p.E25= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs1391797124, COSV53156811; called by muse, mutect2, varscan2
- SELE | c.84G>A p.T28= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as rs754550998, COSV60977447; called by muse, mutect2, varscan2
- SIL1 | c.672C>T p.S224= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as rs932847140, COSV54536517; called by muse, mutect2, varscan2
- SIRPB2 | c.333C>T p.S111= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV63125179; called by muse, mutect2, varscan2
- SLC25A23 | c.975C>T p.I325= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1000951036, COSV51195745; called by muse, mutect2, varscan2
- SLC41A3 | c.1356G>A p.G452= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs747300712, COSV59990133; called by muse, mutect2, varscan2
- SLC44A4 | c.534G>A p.L178= | Silent (SNP) | VAF 106/288 reads (37%) | catalogued as COSV57668888; called by muse, mutect2
- SLIT1 | c.1188C>T p.I396= | Silent (SNP) | VAF 67/242 reads (28%) | catalogued as COSV56597415; called by muse, mutect2, varscan2
- SMAD3 | c.675C>G p.T225= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV59288842; called by mutect2, varscan2
- SMARCC2 | c.2052C>T p.V684= | Silent (SNP) | VAF 55/147 reads (37%) | catalogued as COSV57223965; called by muse, mutect2, varscan2
- SP6 | c.606G>A p.L202= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV60618944; called by muse, mutect2
- SREBF1 | c.1896C>T p.I632= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs17854924, COSV99889475; called by muse, varscan2
- SSX3 | c.321C>A p.I107= | Silent (SNP) | VAF 76/110 reads (69%) | catalogued as COSV53645851; called by muse, mutect2, varscan2
- SVOP | c.1647G>A p.*549= | Silent (SNP) | VAF 88/154 reads (57%) | catalogued as rs566794625, COSV54468399; called by muse, mutect2, varscan2
- TCTN3 | c.846C>T p.V282= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV56450796; called by muse, mutect2, varscan2
- TEK | c.429C>T p.F143= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV66232777; called by muse, mutect2, varscan2
- THBS4 | c.2208G>A p.V736= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV63470654; called by muse, mutect2, varscan2
- THOC3 | c.1002C>T p.D334= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as rs1376581273, COSV54198527; called by muse, mutect2, varscan2
- THSD7A | c.2214C>T p.I738= | Silent (SNP) | VAF 67/133 reads (50%) | catalogued as rs1247786786, COSV70271102; called by muse, mutect2, varscan2
- TLE2 | c.1131C>T p.S377= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV53582787; called by muse, mutect2, varscan2
- TLR8 | c.882C>T p.L294= (on ENST00000218032 / NM_138636.5; = p.L312= on NM_016610.4) | Silent (SNP) | VAF 49/58 reads (84%) | catalogued as COSV54320101; called by muse, mutect2, varscan2
- TMCO2 | c.531G>A p.G177= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV65646979; called by muse, mutect2, varscan2
- TMEM131L | c.4791C>T p.F1597= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV53649622; called by muse, mutect2, varscan2
- TMEM26 | c.507C>T p.I169= | Silent (SNP) | VAF 23/34 reads (68%) | catalogued as COSV53264067; called by muse, mutect2, varscan2
- TNNI1 | c.486G>A p.R162= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV60189330; called by muse, mutect2, varscan2
- TRAV14DV4 | c.96C>T p.F32= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as rs748715034; called by muse, mutect2, varscan2
- TRAV6 | c.135G>A p.Q45= | Silent (SNP) | VAF 16/21 reads (76%) | called by muse, mutect2, varscan2
- TSHZ2 | c.2772C>T p.P924= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV61591000; called by muse, mutect2, varscan2
- TTN | c.19353T>C p.P6451= (on ENST00000591111; = p.P5524= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV60294100; called by muse, mutect2, varscan2
- UGT3A2 | c.1453C>T p.L485= | Silent (SNP) | VAF 42/56 reads (75%) | catalogued as COSV56932946; called by muse, mutect2, varscan2
- USP6NL | c.1800C>T p.S600= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV53214887; called by muse, mutect2, varscan2
- VEGFA | c.696G>A p.R232= (on ENST00000523873 / NM_001171623.1; = p.R395= on NM_003376.6) | Silent (SNP) | VAF 55/197 reads (28%) | catalogued as COSV57878842; called by muse, mutect2, varscan2
- ZAN | c.7779C>T p.V2593= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as rs757439938, COSV100770329; called by muse, mutect2, varscan2
- ZBTB12 | c.714C>T p.S238= | Silent (SNP) | VAF 122/462 reads (26%) | catalogued as COSV64993972; called by muse, mutect2, varscan2
- ZCCHC4 | c.1395G>A p.K465= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV100255583; called by muse, mutect2, varscan2
- ZCCHC4 | c.1396A>C p.R466= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100255586; called by muse, mutect2, varscan2
- ZNF135 | c.996G>A p.G332= (on ENST00000313434 / NM_001289401.2; = p.G344= on NM_003436.4) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV57885237; called by muse, mutect2, varscan2
- ZNF217 | c.888C>T p.F296= | Silent (SNP) | VAF 67/194 reads (35%) | catalogued as COSV56601440; called by muse, mutect2, varscan2
- ZNF366 | c.1812C>T p.F604= | Silent (SNP) | VAF 102/149 reads (68%) | catalogued as COSV59218597; called by muse, mutect2, varscan2
- ZNF446 | c.576C>T p.N192= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs151261644; called by muse, mutect2, varscan2
- ZNF585A | c.606C>T p.F202= (on ENST00000292841 / NM_001288800.2; = p.F147= on NM_152655.3) | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV53066570; called by muse, mutect2, varscan2
- ZNF618 | c.726C>T p.P242= (on ENST00000374126 / NM_001318042.2; = p.P210= on NM_133374.2) | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1482156964, COSV55928210; called by muse, mutect2, varscan2
- ADGRE4P | n.128G>A | RNA (SNP) | VAF 41/150 reads (27%) | called by muse, mutect2, varscan2
- C2orf83 | n.420C>T | RNA (SNP) | VAF 34/138 reads (25%) | catalogued as COSV52312626; called by muse, mutect2, varscan2
- CA6 | c.259+2003C>T | Intron (SNP) | VAF 7/34 reads (21%) | catalogued as rs1287277746, COSV101077699; called by muse, mutect2, varscan2
- CDC42BPA | c.2944-3913G>A | Intron (SNP) | VAF 25/139 reads (18%) | catalogued as COSV100506897; called by muse, mutect2, varscan2
- CX3CR1 | chr3:39281640 G>A | 5'Flank (SNP) | VAF 7/41 reads (17%) | catalogued as COSV64195092; called by muse, mutect2, varscan2
- LASP1 | c.-2C>T | 5'UTR (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100530472; called by muse, mutect2, varscan2
- LASP1 | c.-1C>T | 5'UTR (SNP) | VAF 6/44 reads (14%) | catalogued as rs769364894, COSV100530473; called by mutect2, varscan2
- MASP1 | c.1303+5086C>T | Intron (SNP) | VAF 24/76 reads (32%) | catalogued as COSV99962847; called by muse, mutect2, varscan2
- PREX2 | c.2716-2919A>G | Intron (SNP) | VAF 99/190 reads (52%) | catalogued as COSV99909967; called by muse, mutect2, varscan2
- PRRC2B | c.6226-915T>A | Intron (SNP) | VAF 80/265 reads (30%) | catalogued as COSV100261155; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-45739G>A | Intron (SNP) | VAF 4/13 reads (31%) | catalogued as rs1321578623, COSV101045092, COSV67440815; called by muse, mutect2, varscan2
- TTN | c.10360+2999C>T | Intron (SNP) | VAF 6/22 reads (27%) | catalogued as COSV59908527; called by muse, mutect2, varscan2
- TTN | c.10360+2412T>A | Intron (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100630158; called by muse, mutect2, varscan2
- TTN | c.10360+2411C>A | Intron (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100630159; called by muse, mutect2, varscan2
